Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LN-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries
- 2: SP: Lateral left external iliac lymph nodes
- 3: SP: Left external iliac lymph nodes
- 4: SP: Left obturator lymph nodes
- 5: SP: Left hypogastric lymph nodes
- 6: SP: Left common iliac lymph nodes
- 7: SP: Right external iliac lymph nodes
- 8: SP: Lateral right external iliac lymph nodes
- 9: SP: Right obturator lymph nodes
- 10: SP: Right hypogastric lymph nodes
- 11: SP: Right common iliac lymph nodes

Adenocarcinoma, Endometrioid, Nos 8380/3
Site: Endometrium C54.1

5/1/11

DIAGNOSIS:

- 1) UTERUS, CERVIX, BILATERAL OVARIES AND FALLOPIAN TUBES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID WITH MORULAR SQUAMOUS METAPLASIA, FIGO GRADE I ($\leq$ 6% SOLID GROWTH).
- THE TUMOR SHOWS FOCAL SOLID AREAS WHICH COMPRISE $<$ 5% OF THE TOTAL TUMOR (SEE NOTE), NUCLEAR GRADE 1.
- THE TUMOR IS LIMITED TO THE ENDOMETRIUM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- THE CERVIX SHOWS ENDOMETRIOSIS.
- THE ENDOMETRIUM SHOWS COMPLEX HYPERPLASIA WITH ATYPIA.
- THE MYOMETRIUM SHOWS LEIOMYOMAS.
- BENIGN RIGHT FALLOPIAN TUBE
- THE RIGHT OVARY SHOWS UTERO-OVARIAN ADHESIONS AND TUBO-OVARIAN ADHESIONS.
- BENIGN LEFT FALLOPIAN TUBE WITH A PARATUBAL CYST.
- THE LEFT OVARY SHOWS ENDOSALPINGIOSIS AND TUBO-OVARIAN ADHESIONS.

NOTE: DR. [REDACTED] HAS REVIEWED THIS CASE AND AGREES WITH THE DIAGNOSIS.

- 2) LYMPH NODE, LEFT LATERAL EXTERNAL ILIAC; EXCISION:

** Continued on next page **

[page 2 of 2]
- ONE BENIGN LYMPH NODE, (0/1).
- 3) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION: - FIVE BENIGN LYMPH
NODES (0/5).
- 4) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- EIGHT BENIGN LYMPH NODES (0/8).
- 5) LYMPH NODE, LEFT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPHOID TISSUE SEEN IN THE ENTIRELY SUBMITTED SPECIMEN.
- 7) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION: - SIX BENIGN LYMPH
NODES (0/6).
- 8) LYMPH NODES, RIGHT LATERAL EXTERNAL ILIAC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPHOID TISSUE SEEN IN THE ENTIRELY SUBMITTED SPECIMEN.
- 9) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- TEN BENIGN LYMPH NODES (0/10).
- 10) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPHOID TISSUE SEEN IN THE ENTIRELY SUBMITTED SPECIMEN.
- 11) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Source: NCI Genomic Data Commons file 66708e2e-0914-46f1-aee4-1f34d44ce50d (TCGA-AP-A0LN.D50C7207-D840-48A2-8D73-E1C71FFA73E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).